Surgical pathology report (de-identified scan), TCGA case TCGA-AA-A024, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-A024-01A (Primary Tumor).

TCGA # Internal Sample ID:

Diagnosis:

The material presented is a left hemicolectomy specimen with a moderately differentiated, invasive adenocarcinoma of the colon, G 2, of the type of a mucous carcinoma, with permeation of all wall layers (p T 3), free resection margins, free lymph nodes (p N 0) and an additional tubular adenoma in the mucosal region.

Comment:

Other diverticulum formations were also detectable over the course of the intestine.

ICD-0-3

adenocarcinoma, Nos 8140/3

Site: descending (mucosa) colon C18.2 p 3/30/11

Source: NCI Genomic Data Commons file 3b779807-81b6-4858-9e18-c58c13dc7daf (TCGA-AA-A024.48C27265-38FC-4291-8CB8-B10F577B2FEB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).